Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A2J6, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A2J6-06A (Metastatic).

100-0-3

Melanoma, NOS 8720/3

Site: lymph node, groin C77.4
lw 7/24/11

DIAGNOSIS

Patient ID - Sample ID -

HPV Discrepancy		X

(A) RIGHT SUPERFICIAL GROIN, NODE DISSECTION:

FIVE OUT OF THIRTEEN LYMPH NODES WITH SUBCAPSULAR AND PARENCHYMAL METASTATIC
MALIGNANT MELANOMA (5/13)
LARGEST TUMOR DEPOSIT 44 X 24 MM.
EXTRA NODAL EXTENSION IS PRESENT.

(B) ILIAC AND OBTURATOR LYMPH NODE:

THREE OF TWENTY-TWO LYMPH NODES WITH SUBCAPSULAR AND PARENCHYMAL METASTATIC
MALIGNANT MELANOMA (3/22).
LARGEST MICROSCOPIC FOCUS OF METASTATIC MELANOMA IS 7.0 X 7.0 MM.
EXTRA NODAL EXTENSION IS PRESENT.

In both specimens there is dark, granular pigment consistent with exogenous origin such as tattoo.

Entire report and diagnosis completed by MD

GROSS DESCRIPTION

(A) RIGHT SUPERFICIAL GROIN, NODE DISSECTION - An unremarkable light tan skin ellipse measures 23.5 x 2.8 cm with attached fat, overall 23.5 x 19.0 x 4.0 cm.

Dissection of the fat reveals six grossly positive lymph node metastases with brown pigment. The metastases range in diameter from 4.4 to 0.7 cm.

Tumor is submitted for tumor bank.

INK CODE: None.

SECTION CODE: A1-A2, representative largest lymph node metastasis; A3-A7, additional lymph node metastases, one representative node each; A8, three lymph nodes; A9, two lymph nodes; A10, two possible lymph nodes; A11, two possible lymph nodes; A12, three possible lymph nodes; A13, representative unremarkable skin.

(B) ILIAC AND OBTURATOR LYMPH NODE - A yellow, fibrofatty tissue fragment measures overall 12.0 x 8.0 x 4.0 cm. Twenty-four lymph nodes are identified, 7.0 x 2.5 x 1.5 cm and the smallest 0.3 x 0.3 x 0.3 cm. Multiple lymph nodes are grossly positive with a black surface.

SECTION CODE: B1, representative of largest grossly positive lymph node; B2, representative section of one grossly positive lymph node; B3, representative section of one lymph node; B4, representative section of one lymph node; B5, one lymph node; B6, two lymph nodes; B7, three lymph nodes; B8, two lymph nodes; B9, two lymph nodes; B10, two lymph nodes; B11, six possible lymph nodes; B12, two lymph nodes.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by:
specifically cleared or approved by the U.S. Food and Drug Administration."
Released by:

. These tests have not been

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 2845ed8e-ae77-4406-8989-bf3d92dba9a7 (TCGA-D3-A2J6.2A171FA8-1131-410A-BEDB-EB38849D34A9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).